Somatic mutation profile of tumor specimen TARGET-10-PARCDV-09A (aliquot TARGET-10-PARCDV-09A-01D) from TARGET case TARGET-10-PARCDV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,621 days).
Specimen TARGET-10-PARCDV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dc1b46a-3437-44ff-9944-d7a8ffaff532.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCDV-10A (Blood Derived Normal), aliquot TARGET-10-PARCDV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/091f5434-90b9-485a-91e7-71b255972ec2

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP6 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); catalogued as rs148680131; called by mutect2, varscan2
- H2AC11 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- H2AC8 | c.310dup p.A104Gfs*16 | Frame Shift Ins (INS) | VAF 11/84 reads (13%) | called by mutect2, pindel, varscan2
- SEMA5A | c.2793C>A p.S931= | Silent (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
